Somatic mutation profile of tumor specimen BA2792D (aliquot aq-BA2792D) from BEATAML1.0 case 2166, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Refractory anemia with excess blasts; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.5 years (18,820 days).
Specimen BA2792D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a55ab2fb-2f3e-48c1-b510-c3996e06206f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2219D (Solid Tissue Normal), aliquot aq-BA2219D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/882c6d86-c95c-4fc6-a7c3-e9ba3c4c14e3

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Frame Shift Ins 1, Frame Shift Del 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RIT1 | c.247A>C p.T83P | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs869025195, CM136417; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AP2A2 | c.2762G>A p.R921H | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs371126256; called by muse, mutect2, varscan2
- C6orf58 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as rs780579826, COSV100314770, COSV61667508; called by muse, mutect2, varscan2
- FAM135B | c.4144G>A p.A1382T | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99424665; called by muse, mutect2, varscan2
- RNF225 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs1447686650; called by muse, mutect2
- SLC8A2 | c.2659G>A p.G887S | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52641346; called by muse, varscan2
- WT1 | c.1105_1108dup p.A370Vfs*4 | Frame Shift Ins (INS) | VAF 61/216 reads (28%) | catalogued as COSV60065440; called by mutect2, varscan2
- NAT10 | c.1538del p.D513Vfs*79 | Frame Shift Del (DEL) | VAF 64/206 reads (31%) | called by mutect2, pindel, varscan2
- NLRP13 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 70/140 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOC3L | c.1647C>G p.D549E | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by mutect2, varscan2
- TAS2R38 | c.360G>C p.K120N | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPM4 | c.2132+1G>A p.X711_splice | Splice Site (SNP) | VAF 27/62 reads (44%) | called by muse, mutect2, varscan2
- ANGPTL1 | c.339G>A p.V113= | Silent (SNP) | VAF 78/198 reads (39%) | catalogued as rs867943875, COSV52367519; called by muse, mutect2, varscan2
- GLI4 | c.855C>T p.H285= | Silent (SNP) | VAF 44/96 reads (46%) | catalogued as rs756808026; called by muse, mutect2, varscan2
- LINC02410 | n.340C>T | RNA (SNP) | VAF 15/71 reads (21%) | catalogued as rs889981884; called by muse, mutect2, varscan2
